Somatic mutation profile of tumor specimen TCGA-2A-AAYU-01A (aliquot TCGA-2A-AAYU-01A-11D-A41K-08) from TCGA case TCGA-2A-AAYU, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.4 years (20,582 days).
Specimen TCGA-2A-AAYU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cc6a526-c4f0-437c-9d47-46b1cc9be31d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-AAYU-10A (Blood Derived Normal), aliquot TCGA-2A-AAYU-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecde6fda-84a0-4589-ac65-cf1539841165

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 17, Silent 8, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPTL5 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV57532035; called by muse, mutect2, varscan2
- BANK1 | c.2114A>C p.Q705P | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100536439; called by muse, mutect2, varscan2
- C5 | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99798028; called by muse, mutect2, varscan2
- FLRT2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs754917817, COSV58139180; called by muse, mutect2, varscan2
- GBP6 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100969562; called by muse, mutect2, varscan2
- GPR158 | c.2900C>A p.P967Q | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.084); catalogued as rs368773769; called by muse, mutect2, varscan2
- KRT18 | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.106); catalogued as COSV101184037; called by muse, mutect2, varscan2
- MAGEB6B | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.8); catalogued as rs770913834, COSV69689543; called by muse, mutect2, varscan2
- NETO2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV100292478; called by muse, mutect2, varscan2
- OR4K15 | c.812T>A p.V271D (on ENST00000305051; = p.V247D on NM_001005486.1) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100521047; called by muse, mutect2, varscan2
- PCDH12 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.417); catalogued as rs762470414, COSV51520314; called by muse, mutect2, varscan2
- PCDHB1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs782363571, COSV100128195; called by muse, mutect2, varscan2
- PRSS1 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100298046; called by muse, mutect2, varscan2
- PSME4 | c.4591C>G p.P1531A | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1282992215, COSV101122525; called by muse, mutect2, varscan2
- RYR2 | c.14368C>T p.R4790* | Nonsense Mutation (SNP) | VAF 72/165 reads (44%) | catalogued as COSV63702045; called by muse, mutect2, varscan2
- SCP2 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777327087, COSV101027080; called by muse, mutect2, varscan2
- TENM2 | c.1004C>T p.P335L (on ENST00000518659 / NM_001122679.2; = p.P144L on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1037422619; called by muse, mutect2
- ZSCAN25 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1476203946, COSV99500575; called by muse, mutect2
- DAXX | c.1644del p.N548Kfs*8 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- AZU1 | c.234C>T p.T78= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as rs750313471, COSV99297322; called by muse, mutect2, varscan2
- COL4A2 | c.2520G>A p.L840= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs958605629, COSV100847370; called by muse, mutect2
- DNAH3 | c.9762G>A p.L3254= | Silent (SNP) | VAF 80/181 reads (44%) | catalogued as COSV99767915; called by muse, mutect2, varscan2
- KIF6 | c.1623C>T p.S541= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as COSV99759115; called by muse, mutect2, varscan2
- OLFML1 | c.855G>A p.G285= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100206606; called by muse, mutect2
- RUNX1T1 | c.576G>C p.L192= (on ENST00000265814 / NM_001198628.1; = p.L165= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99752508; called by muse, mutect2
- SLC4A2 | c.3486T>C p.R1162= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV99879798; called by muse, mutect2, varscan2
- YTHDC2 | c.1464C>T p.V488= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV50736604, COSV99363404; called by muse, mutect2, varscan2
